Gene-level copy-number profile of tumor specimen TCGA-77-8148-01A from TCGA case TCGA-77-8148, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.2 years (24,918 days).
Specimen TCGA-77-8148-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.beead30a-a3af-4eae-9499-d83ba1eb4d82.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8148-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cfbdb12-7686-4022-b1ef-33055dd8b385

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 619; copy number 2: 12,084; copy number 3: 17,711; copy number 4: 11,702; copy number 5: 12,119; copy number 6: 3,363; copy number 7: 856; copy number 8: 627; copy number 9: 191; copy number 10: 173; copy number 12: 222; copy number 29: 80; copy number 40: 9; copy number 47: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8148-01A-11D-2243-01): tumor purity 0.68, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–3): MTAP, AL359922.1.
- chr9:21,892,188–22,128,103, 9 genes (within-gene range 0–3): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,198 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:48,809,340–49,419,013, 1 gene, copy number 8 (within-gene range 6–8): AC009975.1.
- chr2:48,962,157–66,200,373, 254 genes, copy number 8 (within-gene range 5–9) (broad region; genes not listed).
- chr3:93,843,764–117,544,311, 322 genes, copy number 7–9 (broad region; genes not listed).
- chr3:165,772,904–173,336,965, 124 genes, copy number 10 (broad region; genes not listed).
- chr3:173,644,231–173,644,711, 1 gene, copy number 10: AC092967.1.
- chr3:175,675,087–183,428,778, 129 genes, copy number 29–47 (within-gene range 6–47) (broad region; genes not listed).
- chr7:53,316,149–56,848,800, 100 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:31,639,222–32,855,666, 7 genes, copy number 8 (within-gene range 2–8): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1.
- chr8:34,174,886–40,901,854, 118 genes, copy number 7 (broad region; genes not listed).
- chr8:123,400,582–145,066,685, 408 genes, copy number 7–8 (broad region; genes not listed).
- chr9:76,611,376–78,031,811, 18 genes, copy number 7: PRUNE2, PCA3, AL359314.1, AL390239.1, AL353637.2, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2, ATP5MFP3, RFC5P1, VPS13A-AS1, VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P, GNAQ.
- chr11:69,909,184–72,080,693, 72 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr14:20,090,130–21,351,301, 88 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr14:77,800,109–77,935,014, 1 gene, copy number 8 (within-gene range 4–8): ADCK1.
- chr16:55,259,969–55,833,337, 18 genes, copy number 8: AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1, CES1.
- chr17:26,981,694–27,626,438, 21 genes, copy number 8: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1.
- chr17:27,625,484–27,626,438, 1 gene, copy number 8: AC015688.6.
- chr17:28,328,325–29,180,398, 74 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:27,638,483–39,642,401, 441 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 618. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
